Somatic mutation profile of tumor specimen TCGA-CF-A9FH-01A (aliquot TCGA-CF-A9FH-01A-11D-A38G-08) from TCGA case TCGA-CF-A9FH, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: Low Grade; Age at diagnosis: 85.5 years (31,236 days).
Specimen TCGA-CF-A9FH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c5a4c3bc-639f-47df-971a-ff06efecd7c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CF-A9FH-10A (Blood Derived Normal), aliquot TCGA-CF-A9FH-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d433bcf3-bd68-4769-b4c1-0d20d044b460

The open-access MAF lists 36 somatic variants for this specimen: 28 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 6, Nonsense Mutation 3, Frame Shift Ins 2, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.*167A>T | 3'UTR (SNP) | VAF 164/173 reads (95%) | catalogued as rs121913484, CM950471, COSV53390047; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- IKZF1 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770551610, CM166266, CM166267, COSV58781145; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KLHL3 | c.1480G>A p.A494T | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as rs199469633, CM120723, COSV59050916; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS18 | c.1991G>A p.R664H | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs758594316, COSV51398250; called by muse, mutect2, varscan2
- ALG8 | c.1142A>T p.H381L | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55199229; called by muse, mutect2, varscan2
- CAMTA1 | c.4771C>T p.Q1591* | Nonsense Mutation (SNP) | VAF 154/308 reads (50%) | catalogued as COSV100346330; called by muse, mutect2, varscan2
- CDK12 | c.1243A>G p.M415V | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV70999294; called by muse, mutect2, varscan2
- CHD4 | c.5332T>G p.L1778V (on ENST00000357008 / NM_001363606.2; = p.L1789V on NM_001273.5) | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV58894879; called by muse, mutect2, varscan2
- EGR1 | c.407G>T p.R136L | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1359191813, COSV53517981; called by muse, mutect2
- LILRA4 | c.860G>T p.R287L | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as COSV52490304, COSV52493488; called by muse, varscan2
- MTUS2 | c.638G>A p.G213E | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0.018); catalogued as rs1251974794, COSV70913471; called by muse, mutect2, varscan2
- NR5A2 | c.688T>A p.L230M (on ENST00000367362 / NM_205860.3; = p.L184M on NM_003822.5) | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as COSV52645203; called by muse, mutect2, varscan2
- NUTM1 | c.515T>G p.I172S | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.235); catalogued as COSV61545926; called by muse, mutect2, varscan2
- OR4A16 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 77/171 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.082); catalogued as rs779328620, COSV59041859, COSV59045144; called by muse, mutect2, varscan2
- PCDH11X | c.2806G>T p.A936S | Missense Mutation (SNP) | VAF 103/131 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53443091; called by muse, mutect2, varscan2
- PDGFB | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs748590340, COSV58645758; called by muse, mutect2, varscan2
- PIKFYVE | c.740A>C p.D247A | Missense Mutation (SNP) | VAF 55/122 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as COSV52237012; called by muse, mutect2, varscan2
- PINK1 | c.717G>T p.Q239H | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.541); catalogued as rs1429153319, COSV100387170; called by muse, mutect2, varscan2
- PRDX2 | c.164T>G p.I55S | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1006913681, COSV56877315; called by muse, mutect2, varscan2
- PREX2 | c.650A>T p.Q217L | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); catalogued as rs1275972126, COSV55750939; called by muse, mutect2, varscan2
- PRSS35 | c.179C>T p.T60I | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV63800103; called by muse, mutect2, varscan2
- REL | c.1073G>C p.R358T | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs1178670837, COSV54362380; called by muse, mutect2, varscan2
- RICTOR | c.3328C>T p.R1110C | Missense Mutation (SNP) | VAF 68/149 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs748585755, COSV57117133; called by muse, mutect2, varscan2
- RYR2 | c.10516C>T p.R3506* | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as rs777431224, COSV63702683; called by muse, mutect2, varscan2
- SNX33 | c.29A>G p.D10G | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as rs1191958442, COSV57912767; called by muse, mutect2, varscan2
- TRPA1 | c.937C>T p.L313F | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51555527, COSV51556846; called by muse, mutect2, varscan2
- TSC1 | c.2791G>T p.E931* | Nonsense Mutation (SNP) | VAF 82/88 reads (93%) | catalogued as COSV100051127; called by muse, mutect2, varscan2
- H2AC21 | c.335_336insTT p.Q113Sfs*21 | Frame Shift Ins (INS) | VAF 37/99 reads (37%) | called by mutect2, pindel, varscan2
- SPTAN1 | c.913dup p.A305Gfs*13 | Frame Shift Ins (INS) | VAF 64/95 reads (67%) | called by mutect2, pindel, varscan2
- COL21A1 | c.2151A>G p.R717= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs1303253274, COSV99777465; called by muse, mutect2, varscan2
- CPNE9 | c.804A>G p.K268= | Silent (SNP) | VAF 33/59 reads (56%) | catalogued as rs1223941041, COSV56067646; called by muse, mutect2, varscan2
- CUX2 | c.2619G>A p.P873= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs1159968165, COSV55624584; called by muse, mutect2, varscan2
- DNAH17 | c.9972G>A p.A3324= | Silent (SNP) | VAF 120/182 reads (66%) | catalogued as rs1198992662, COSV67749829; called by muse, mutect2, varscan2
- OR6A2 | c.165C>A p.T55= | Silent (SNP) | VAF 39/44 reads (89%) | catalogued as COSV60264425; called by muse, mutect2, varscan2
- RAPGEF3 | c.2283C>T p.L761= (on ENST00000389212; = p.L719= on NM_006105.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/73 reads (48%) | catalogued as rs1415048214, COSV50198052; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504678 A>G | 5'Flank (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2, varscan2
